Somatic mutation profile of tumor specimen HTMCP-03-06-02360-01A (aliquot HTMCP-03-06-02360-01A-01D-9392) from CGCI case HTMCP-03-06-02360, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 70.3 years (25,669 days).
Specimen HTMCP-03-06-02360-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3f31346-39e5-478f-a90f-d7602ce9e42c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02360-10A (Blood Derived Normal), aliquot HTMCP-03-06-02360-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/016aa050-2909-4dca-a6f3-c73e285a6b24

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 44/52 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CADPS | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768044590, COSV99032486; called by muse, mutect2, varscan2
- CCDC183 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761372377; called by muse, mutect2, varscan2
- CELSR3 | c.2984G>A p.R995Q | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs774391743; called by muse, mutect2, varscan2
- CUX1 | c.1537C>G p.R513G (on ENST00000437600 / NM_181500.4; = p.R515G on NM_001913.5) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52927713; called by muse, mutect2, varscan2
- FAM193A | c.2929G>T p.E977* | Nonsense Mutation (SNP) | VAF 62/80 reads (78%) | catalogued as COSV100219601; called by muse, mutect2, varscan2
- KANSL1 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 161/337 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV52272425; called by muse, mutect2, varscan2
- MSH4 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs146479652; called by muse, mutect2, varscan2
- PLXNA1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs575140971; called by muse, mutect2, varscan2
- SMARCC2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV57220841; called by muse, mutect2, varscan2
- UBTF | c.1457A>G p.K486R | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs370582103; called by muse, mutect2, varscan2
- WAPL | c.2587G>A p.V863M | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as rs1428769249; called by muse, mutect2, varscan2
- ZFYVE26 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs753557379; called by muse, mutect2, varscan2
- ABCA6 | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APOB | c.2371G>T p.D791Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BIRC6 | c.9700+5G>A | Splice Region (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- CEP135 | c.3322G>A p.E1108K | Missense Mutation (SNP) | VAF 86/148 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PDZD7 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLITRK5 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- YY1 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); called by muse, mutect2
- ABCA8 | c.1377C>T p.A459= | Silent (SNP) | VAF 53/110 reads (48%) | catalogued as rs150896792; called by muse, mutect2, varscan2
- NOS3 | c.2229C>T p.G743= | Silent (SNP) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- TTN | c.95334T>C p.D31778= (on ENST00000591111; = p.D24354= on NM_003319.4) | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs727505046; ClinVar: likely benign; called by muse, mutect2, varscan2
